Somatic mutation profile of tumor specimen C3L-02617-03 (aliquot CPT0229190006) from CPTAC case C3L-02617, project CPTAC-3 (Larynx — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 64.9 years (23,710 days).
Specimen C3L-02617-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Larynx; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 66a5fa66-7825-44e3-88c3-bc08e06bd20e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02617-31 (Blood Derived Normal), aliquot CPT0229330002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b2ff88b2-ed27-4fe3-bf11-e0d9aad9be37

The open-access MAF lists 547 somatic variants for this specimen: 378 protein-altering or splice-affecting, 112 silent, 57 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 324, Silent 112, Intron 25, Nonsense Mutation 21, Splice Site 11, 3'UTR 9, Frame Shift Del 8, RNA 8, 5'UTR 6, Splice Region 6, Frame Shift Ins 5, 3'Flank 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.151-1G>C p.X51_splice | Splice Site (SNP) | VAF 141/341 reads (41%) | hotspot (GDC flag); catalogued as rs730881677, CS014428, CS067079, COSV58682903, COSV58695350, COSV58708670, COSV58717973; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.176C>G p.S59* | Nonsense Mutation (SNP) | VAF 6/16 reads (38%) | catalogued as rs1060500116, CM043772, CM110148, COSV64294267, COSV64296058, COSV64298758; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.743G>T p.R248L | Missense Mutation (SNP) | VAF 104/373 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AATK | c.785C>T p.T262M (on ENST00000326724 / NM_001080395.3; = p.T159M on NM_004920.2) | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs774654612; called by muse, mutect2, varscan2
- AC023055.1 | c.1250A>G p.Q417R | Missense Mutation (SNP) | VAF 62/219 reads (28%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.492); catalogued as rs143656571; called by muse, mutect2, varscan2
- ACTRT1 | c.149G>A p.R50K | Missense Mutation (SNP) | VAF 44/71 reads (62%) | SIFT tolerated (0.13); PolyPhen benign (0.129); catalogued as rs772248403, COSV100947591; called by muse, mutect2, varscan2
- ADAMTS12 | c.1324C>A p.R442S | Missense Mutation (SNP) | VAF 36/161 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61280531; called by muse, mutect2, varscan2
- AJAP1 | c.347G>A p.G116E | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as rs763392397; called by muse, mutect2, varscan2
- AOC1 | c.1493G>A p.G498D | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1268238024, COSV100710841; called by muse, mutect2, varscan2
- APC | c.2738A>G p.H913R | Missense Mutation (SNP) | VAF 55/115 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as rs762572576; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARHGEF25 | c.1639G>T p.G547C | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.111); catalogued as COSV99677967; called by muse, mutect2, varscan2
- BMS1 | c.3599G>C p.R1200P | Missense Mutation (SNP) | VAF 40/88 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.766); catalogued as COSV65732794, COSV65733808; called by muse, mutect2, varscan2
- BRD4 | c.2006G>T p.R669L | Missense Mutation (SNP) | VAF 70/207 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99649791; called by muse, mutect2, varscan2
- C2CD5 | c.1334C>T p.T445I | Missense Mutation (SNP) | VAF 56/204 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.01); catalogued as rs564104874; called by muse, mutect2, varscan2
- CACNA1A | c.1989+1G>T p.X663_splice | Splice Site (SNP) | VAF 28/84 reads (33%) | catalogued as COSV64210471; called by muse, mutect2, varscan2
- CACNA1G | c.2485G>A p.G829S | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs766342903, COSV104415863; called by muse, mutect2
- CAMK2D | c.38A>G p.E13G | Missense Mutation (SNP) | VAF 121/292 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.329); catalogued as rs1344581184; called by muse, mutect2, varscan2
- CASS4 | c.811del p.A271Lfs*24 | Frame Shift Del (DEL) | VAF 42/190 reads (22%) | catalogued as COSV64386420, COSV64386735, COSV64386803; called by mutect2, pindel*, varscan2
- CCT8L2 | c.252C>G p.H84Q | Missense Mutation (SNP) | VAF 83/226 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV63463808; called by muse, mutect2, varscan2
- CDCP1 | c.2387G>T p.R796L | Missense Mutation (SNP) | VAF 106/267 reads (40%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV99944373; called by muse, mutect2, varscan2
- CFAP44 | c.2491C>T p.R831* | Nonsense Mutation (SNP) | VAF 39/76 reads (51%) | catalogued as rs1450437694, COSV55610505; called by muse, mutect2, varscan2
- CMPK2 | c.741C>G p.I247M | Missense Mutation (SNP) | VAF 61/233 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.02); catalogued as COSV56774450; called by muse, mutect2, varscan2
- CSMD1 | c.3155C>T p.P1052L (on ENST00000520002; = p.P1051L on NM_033225.6) | Missense Mutation (SNP) | VAF 50/119 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1388594836; called by muse, mutect2, varscan2
- CSMD3 | c.10168A>T p.T3390S (on ENST00000297405 / NM_001363185.1; = p.T3221S on NM_052900.3) | Missense Mutation (SNP) | VAF 55/254 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.012); catalogued as COSV99821379; called by muse, mutect2, varscan2
- CSMD3 | c.7460G>A p.S2487N (on ENST00000297405 / NM_001363185.1; = p.S2383N on NM_052900.3) | Missense Mutation (SNP) | VAF 50/222 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.201); catalogued as COSV99833100; called by muse, mutect2, varscan2
- CSN1S2AP | n.216-3T>C | Splice Region (SNP) | VAF 23/53 reads (43%) | catalogued as rs1377066493; called by muse, mutect2, varscan2
- DCC | c.152C>T p.T51I | Missense Mutation (SNP) | VAF 61/172 reads (35%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.686); catalogued as COSV59125705; called by muse, mutect2, varscan2
- DCLK3 | c.863G>T p.R288L | Missense Mutation (SNP) | VAF 76/182 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs756312043, COSV69363422; called by muse, varscan2
- DCLRE1A | c.2602_2603del p.L868Kfs*24 | Frame Shift Del (DEL) | VAF 43/155 reads (28%) | catalogued as rs1439483798; called by pindel, varscan2
- DDX60 | c.2574+2T>C p.X858_splice | Splice Site (SNP) | VAF 24/54 reads (44%) | catalogued as COSV67095793; called by muse, mutect2, varscan2
- DIPK1C | c.601C>A p.L201M | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.139); catalogued as COSV59726323; called by muse, mutect2, varscan2
- DMXL2 | c.1912C>A p.L638I | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.2); catalogued as rs142770613; called by muse, mutect2, varscan2
- DNAH11 | c.5633C>T p.T1878I | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1449566001; called by muse, mutect2, varscan2
- DNAH6 | c.1489A>G p.T497A | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as rs1463899013, COSV52877279; called by muse, mutect2, varscan2
- DPP10 | c.44C>A p.P15H | Missense Mutation (SNP) | VAF 69/276 reads (25%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.456); catalogued as COSV69753958; called by muse, mutect2, varscan2
- DPP6 | c.2113C>A p.R705S (on ENST00000377770 / NM_001364500.2; = p.R643S on NM_001936.5) | Missense Mutation (SNP) | VAF 60/197 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59604879; called by muse, mutect2, varscan2
- EPN1 | c.421C>T p.R141W | Missense Mutation (SNP) | VAF 111/464 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs754419293; called by muse, mutect2, varscan2
- EYS | c.1460G>T p.G487V | Missense Mutation (SNP) | VAF 64/274 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.497); catalogued as COSV100677217, COSV60984721; called by mutect2, varscan2
- FAT3 | c.5255A>T p.N1752I | Missense Mutation (SNP) | VAF 36/131 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV53117267; called by muse, mutect2, varscan2
- FBP2 | c.164C>A p.A55D | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.156); catalogued as rs771646420, COSV64694810; called by muse, mutect2
- FCRL5 | c.1841C>T p.S614F | Missense Mutation (SNP) | VAF 39/164 reads (24%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.672); catalogued as COSV62518184; called by muse, mutect2, varscan2
- FREM2 | c.4013C>A p.S1338Y | Missense Mutation (SNP) | VAF 90/194 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as rs776270680, COSV54841142; called by muse, mutect2, varscan2
- GLYATL1 | c.550G>A p.D184N (on ENST00000317391 / NM_001354699.1; = p.D215N on NM_080661.4) | Missense Mutation (SNP) | VAF 72/250 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.114); catalogued as rs953629981; called by muse, mutect2, varscan2
- GSTT2B | c.715C>T p.R239* | Nonsense Mutation (SNP) | VAF 60/160 reads (38%) | catalogued as rs1332115451; called by mutect2, varscan2
- H2BC1 | c.70C>T p.Q24* | Nonsense Mutation (SNP) | VAF 42/152 reads (28%) | catalogued as rs1315927495; called by muse, mutect2, varscan2
- HSF2 | c.373G>C p.D125H | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); catalogued as COSV63773892, COSV63774518; called by muse, mutect2, varscan2
- IGF1R | c.1664A>G p.D555G | Missense Mutation (SNP) | VAF 127/297 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.056); catalogued as COSV51304430; called by muse, mutect2, varscan2
- IL10RA | c.358G>A p.V120M | Missense Mutation (SNP) | VAF 136/483 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as rs1272104522; called by muse, mutect2, varscan2
- IQCJ | c.449T>G p.I150R | Missense Mutation (SNP) | VAF 32/128 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.094); catalogued as COSV67335002; called by muse, mutect2, varscan2
- IRS4 | c.2612del p.G871Dfs*77 | Frame Shift Del (DEL) | VAF 143/284 reads (50%) | catalogued as COSV64534567; called by mutect2, pindel, varscan2
- ITPRID1 | c.515G>C p.G172A | Missense Mutation (SNP) | VAF 110/421 reads (26%) | SIFT tolerated (0.41); PolyPhen benign (0.079); catalogued as COSV60080659; called by muse, mutect2, varscan2
- JAK1 | c.22G>C p.E8Q | Missense Mutation (SNP) | VAF 32/122 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.055); catalogued as COSV61096883; called by muse, mutect2, varscan2
- KCND2 | c.1735A>T p.K579* | Nonsense Mutation (SNP) | VAF 57/216 reads (26%) | catalogued as COSV100478421; called by muse, mutect2, varscan2
- KEAP1 | c.1105G>T p.V369L | Missense Mutation (SNP) | VAF 50/187 reads (27%) | SIFT tolerated (0.36); PolyPhen benign (0.029); catalogued as COSV50386938, COSV50609562, COSV99061730; called by muse, mutect2, varscan2
- KIR2DS4 | c.446G>A p.C149Y | Missense Mutation (SNP) | VAF 100/366 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs746437419; called by muse, mutect2, varscan2
- KMT2A | c.9733C>T p.P3245S | Missense Mutation (SNP) | VAF 71/258 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.996); catalogued as COSV63290360; called by muse, mutect2, varscan2
- KMT2C | c.12667-1G>T p.X4223_splice | Splice Site (SNP) | VAF 23/82 reads (28%) | catalogued as COSV51489875; called by muse, mutect2, varscan2
- LBP | c.275C>A p.A92E | Missense Mutation (SNP) | VAF 31/129 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.111); catalogued as COSV54139557; called by muse, mutect2, varscan2
- LOXHD1 | c.2430C>G p.I810M | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.804); catalogued as COSV59662201; called by muse, mutect2, varscan2
- LRP1B | c.10267G>T p.G3423C | Missense Mutation (SNP) | VAF 33/108 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101260356, COSV67212758; called by muse, mutect2, varscan2
- LRP6 | c.1022G>C p.R341P | Missense Mutation (SNP) | VAF 70/223 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.312); catalogued as COSV53786736; called by muse, mutect2, varscan2
- LRRC34 | c.1267C>T p.R423C (on ENST00000446859 / NM_001172779.2; = p.R391C on NM_153353.5) | Missense Mutation (SNP) | VAF 46/237 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as rs199832335; called by muse, mutect2, varscan2
- LRRK2 | c.2842C>T p.R948* | Nonsense Mutation (SNP) | VAF 11/49 reads (22%) | catalogued as rs766809708, COSV54157381, COSV54161437; called by muse, mutect2, varscan2
- MAP3K5 | c.3002G>T p.R1001I | Missense Mutation (SNP) | VAF 77/279 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.462); catalogued as rs1282787956; called by muse, mutect2, varscan2
- MAPT | c.2456C>A p.T819K (on ENST00000262410 / NM_001377265.1; = p.T427K on NM_005910.5) | Missense Mutation (SNP) | VAF 137/479 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs63750991, CM043765, COSV52239106; called by muse, mutect2, varscan2
- MAST2 | c.4276C>T p.R1426C | Missense Mutation (SNP) | VAF 94/316 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.893); catalogued as rs773799954; called by muse, mutect2
- MBLAC1 | c.598G>A p.E200K | Missense Mutation (SNP) | VAF 153/492 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.056); catalogued as rs753136685, COSV53543214, COSV99498920; called by muse, mutect2, varscan2
- MCMDC2 | c.317C>A p.P106H | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58034763; called by muse, mutect2, varscan2
- MEP1A | c.2026C>G p.P676A | Missense Mutation (SNP) | VAF 160/596 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV57921717; called by muse, mutect2, varscan2
- MIEF1 | c.1348C>G p.L450V | Missense Mutation (SNP) | VAF 56/193 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100307843, COSV100307906; called by muse, mutect2, varscan2
- MLH1 | c.1591G>A p.V531M | Missense Mutation (SNP) | VAF 28/223 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764663152; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MRPS18B | c.407A>G p.Y136C | Missense Mutation (SNP) | VAF 98/341 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as rs200954069; called by muse, mutect2, varscan2
- MYH1 | c.2975C>A p.T992N | Missense Mutation (SNP) | VAF 116/432 reads (27%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs563867561; called by muse, mutect2, varscan2
- MYOM1 | c.4561C>T p.P1521S | Missense Mutation (SNP) | VAF 87/171 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55296651; called by muse, mutect2, varscan2
- NACC2 | c.460G>A p.A154T | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs1564231038; called by muse, mutect2, varscan2
- NBAS | c.4097A>G p.Y1366C | Missense Mutation (SNP) | VAF 37/132 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1331848647; called by muse, mutect2, varscan2
- NCKAP1L | c.760G>A p.E254K | Missense Mutation (SNP) | VAF 6/117 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.331); catalogued as COSV53206940; called by muse, mutect2
- NCOR1 | c.3671-1G>T p.X1224_splice | Splice Site (SNP) | VAF 18/57 reads (32%) | catalogued as COSV51988397; called by muse, mutect2
- NLRP11 | c.241C>A p.L81I | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1458601068, COSV100789705; called by muse, mutect2, varscan2
- NOBOX | c.98C>A p.A33D | Missense Mutation (SNP) | VAF 108/329 reads (33%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.015); catalogued as COSV56194147; called by muse, mutect2, varscan2
- NOTCH1 | c.1264C>T p.P422S | Missense Mutation (SNP) | VAF 137/435 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV53052320, COSV99490172; called by muse, mutect2, varscan2
- NPAT | c.4197G>T p.K1399N | Missense Mutation (SNP) | VAF 36/145 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV53721814; called by muse, mutect2, varscan2
- NPY1R | c.376G>T p.V126L | Missense Mutation (SNP) | VAF 78/226 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV56715081; called by muse, mutect2, varscan2
- NPY2R | c.652G>C p.V218L | Missense Mutation (SNP) | VAF 91/218 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV61527135; called by muse, mutect2, varscan2
- NTAQ1 | c.514A>G p.K172E | Missense Mutation (SNP) | VAF 32/115 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.151); catalogued as rs769560639; called by muse, mutect2, varscan2
- OR13G1 | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 72/210 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.348); catalogued as rs1333301269, COSV100687562; called by muse, mutect2, varscan2
- OR2T1 | c.68C>A p.S23* | Nonsense Mutation (SNP) | VAF 47/196 reads (24%) | catalogued as COSV63542638; called by muse, mutect2, varscan2
- OR4A16 | c.707C>T p.P236L | Missense Mutation (SNP) | VAF 73/228 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV100125091; called by muse, mutect2, varscan2
- OR4C16 | c.316G>T p.G106C | Missense Mutation (SNP) | VAF 78/202 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100113928, COSV58940728; called by muse, mutect2, varscan2
- OR52N2 | c.499C>G p.R167G | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.055); catalogued as COSV57678087; called by muse, mutect2, varscan2
- OR6N1 | c.728C>A p.S243Y | Missense Mutation (SNP) | VAF 31/123 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58648637; called by muse, mutect2, varscan2
- PARD3 | c.956G>T p.R319L | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs779397128; called by muse, mutect2, varscan2
- PEG3 | c.4270G>T p.G1424W | Missense Mutation (SNP) | VAF 97/264 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1215749606, COSV99690876; called by muse, mutect2, varscan2
- PHOX2B | c.148A>G p.T50A | Missense Mutation (SNP) | VAF 69/197 reads (35%) | SIFT tolerated (0.56); PolyPhen benign (0.005); catalogued as rs1215649814; called by muse, mutect2, varscan2
- PKN1 | c.2131G>A p.V711M | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs367610820; called by muse, mutect2, varscan2
- PNPLA6 | c.2215G>T p.V739L (on ENST00000414982 / NM_001166111.2; = p.V691L on NM_006702.5) | Missense Mutation (SNP) | VAF 105/682 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as COSV55378662; called by muse, mutect2, varscan2
- PPP1R1A | c.233C>A p.T78K | Missense Mutation (SNP) | VAF 87/303 reads (29%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.936); catalogued as COSV99226418; called by muse, mutect2, varscan2
- PPP2R1A | c.745C>T p.R249C | Missense Mutation (SNP) | VAF 36/114 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.018); catalogued as COSV100436305; called by muse, mutect2, varscan2
- PRUNE2 | c.3944C>A p.P1315Q | Missense Mutation (SNP) | VAF 56/210 reads (27%) | SIFT tolerated (0.4); PolyPhen benign (0.014); catalogued as rs1282416116; called by muse, mutect2, varscan2
- PXDNL | c.3337del p.A1113Hfs*10 | Frame Shift Del (DEL) | VAF 55/173 reads (32%) | catalogued as COSV62497290; called by mutect2, pindel, varscan2
- RASA1 | c.1136C>G p.S379* | Nonsense Mutation (SNP) | VAF 44/132 reads (33%) | catalogued as COSV57194016; called by muse, mutect2, varscan2
- RASGRP3 | c.1875G>C p.W625C (on ENST00000402538 / NM_001349975.2; = p.W624C on NM_015376.2 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 102/293 reads (35%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.994); catalogued as COSV67821732; called by muse, mutect2, varscan2
- RELN | c.8639C>A p.P2880Q | Missense Mutation (SNP) | VAF 52/187 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs1562855239; called by muse, mutect2, varscan2
- REXO1 | c.1778C>T p.A593V | Missense Mutation (SNP) | VAF 90/321 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs199974482; called by muse, varscan2
- REXO1 | c.1777G>T p.A593S | Missense Mutation (SNP) | VAF 88/315 reads (28%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as rs201699355, COSV50080482; called by muse, varscan2
- RYR2 | c.7375G>T p.G2459W | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV63722412; called by muse, mutect2, varscan2
- SASH1 | c.1234G>C p.D412H | Missense Mutation (SNP) | VAF 51/269 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100821435; called by muse, mutect2, varscan2
- SCYL2 | c.796A>G p.I266V | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs759476790; called by muse, mutect2, varscan2
- SERPINB2 | c.1013C>G p.A338G | Missense Mutation (SNP) | VAF 52/164 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99449095; called by muse, mutect2, varscan2
- SERPIND1 | c.390C>A p.N130K | Missense Mutation (SNP) | VAF 60/169 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53138191; called by muse, mutect2, varscan2
- SIGLEC8 | c.1088C>T p.A363V | Missense Mutation (SNP) | VAF 45/244 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.399); catalogued as COSV58471943; called by muse, mutect2, varscan2
- SLC22A16 | c.313A>G p.K105E | Missense Mutation (SNP) | VAF 117/397 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.115); catalogued as rs750485928; called by muse, mutect2, varscan2
- SLC26A4 | c.258T>A p.S86R | Missense Mutation (SNP) | VAF 150/490 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.833); catalogued as rs756147163; called by muse, mutect2, varscan2
- SLC2A13 | c.299G>T p.G100V | Missense Mutation (SNP) | VAF 86/327 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99785738; called by muse, mutect2, varscan2
- SPATA31D1 | c.2833C>A p.P945T | Missense Mutation (SNP) | VAF 48/133 reads (36%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.627); catalogued as COSV100782644; called by muse, mutect2, varscan2
- SPTA1 | c.4323A>T p.K1441N | Missense Mutation (SNP) | VAF 61/267 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.491); catalogued as COSV63752765; called by muse, mutect2, varscan2
- SPTBN1 | c.1898G>A p.R633H | Missense Mutation (SNP) | VAF 28/362 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.082); catalogued as rs752181604, COSV61687988; called by muse, mutect2
- SYNE1 | c.18871G>A p.A6291T (on ENST00000367255 / NM_182961.4; = p.A6220T on NM_033071.3) | Missense Mutation (SNP) | VAF 59/267 reads (22%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs143594709, COSV54968800; ClinVar: uncertain significance / benign; called by muse, mutect2, varscan2
- TAFA1 | c.182G>C p.R61P | Missense Mutation (SNP) | VAF 61/156 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101524442; called by muse, mutect2, varscan2
- TMEM132C | c.724G>C p.A242P | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT tolerated (0.51); PolyPhen benign (0.031); catalogued as rs776599843; called by muse, mutect2, varscan2
- TP53 | c.166G>T p.E56* | Nonsense Mutation (SNP) | VAF 84/273 reads (31%) | catalogued as COSV52771366, COSV52826932, COSV52883452; called by muse, mutect2, varscan2
- TRHR | c.523A>G p.I175V | Missense Mutation (SNP) | VAF 79/273 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100305058; called by muse, mutect2, varscan2
- UBE2NL | c.164G>T p.R55L | Missense Mutation (SNP) | VAF 99/168 reads (59%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs781838711; called by muse, mutect2, varscan2
- UGT2A3 | c.440T>C p.L147P | Missense Mutation (SNP) | VAF 34/144 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs1296378389; called by muse, mutect2, varscan2
- URGCP | c.400A>G p.M134V (on ENST00000453200 / NM_001077663.3; = p.M125V on NM_017920.4) | Missense Mutation (SNP) | VAF 106/310 reads (34%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs768812049; called by muse, mutect2, varscan2
- USH2A | c.6047C>G p.T2016R | Missense Mutation (SNP) | VAF 53/243 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as rs750260175; called by muse, mutect2, varscan2
- WASHC2C | c.1391C>T p.S464L | Missense Mutation (SNP) | VAF 26/510 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.027); catalogued as rs782105827; called by muse, mutect2
- WT1 | c.906G>T p.M302I | Missense Mutation (SNP) | VAF 70/263 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.923); catalogued as COSV100187968, COSV60067845; called by muse, mutect2, varscan2
- ZBED1 | c.103G>A p.A35T | Missense Mutation (SNP) | VAF 48/400 reads (12%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as rs1170638506, COSV58130147; called by muse, mutect2, varscan2
- ZFHX4 | c.1885G>T p.G629C | Missense Mutation (SNP) | VAF 34/121 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1425725559, COSV99265674; called by muse, mutect2, varscan2
- ZFP37 | c.1034G>T p.G345V | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs768318480; called by muse, mutect2, varscan2
- ZNF10 | c.485G>A p.R162K | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV50216303; called by muse, mutect2, varscan2
- ZNF121 | c.208G>A p.A70T | Missense Mutation (SNP) | VAF 60/193 reads (31%) | SIFT tolerated (0.75); PolyPhen benign (0.041); catalogued as COSV104412353; called by muse, mutect2, varscan2
- ZNF136 | c.899G>T p.R300I | Missense Mutation (SNP) | VAF 49/172 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.247); catalogued as COSV59710729, COSV59711667; called by muse, mutect2, varscan2
- ZNF277 | c.847G>T p.E283* | Nonsense Mutation (SNP) | VAF 35/131 reads (27%) | catalogued as COSV62463700; called by muse, mutect2, varscan2
- ZNF493 | c.1517G>T p.C506F | Missense Mutation (SNP) | VAF 85/333 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100828850; called by muse, mutect2, varscan2
- ZNF496 | c.784+5G>A | Splice Region (SNP) | VAF 34/134 reads (25%) | catalogued as COSV99665043; called by muse, mutect2, varscan2
- ZNF572 | c.727C>G p.P243A | Missense Mutation (SNP) | VAF 63/273 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100073952; called by muse, mutect2, varscan2
- ZNF716 | c.304G>T p.G102C | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as COSV101348596; called by muse, mutect2, varscan2
- ZNF845 | c.1901C>T p.P634L | Missense Mutation (SNP) | VAF 28/126 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as rs143890862; called by muse, mutect2, varscan2
- ABCA4 | c.1638G>T p.M546I | Missense Mutation (SNP) | VAF 26/730 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.001); called by muse, mutect2
- AC105001.2 | c.341A>T p.E114V | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AC244258.1 | n.497T>G | Splice Region (SNP) | VAF 21/87 reads (24%) | called by muse, mutect2
- ADAMTS3 | c.2929G>C p.E977Q | Missense Mutation (SNP) | VAF 233/386 reads (60%) | SIFT tolerated (1); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ADCY3 | c.2671_2673dup p.L891dup | In Frame Ins (INS) | VAF 49/231 reads (21%) | called by mutect2, pindel, varscan2
- ADGB | c.4244G>A p.G1415E | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ADGRB1 | c.1092C>A p.S364R | Missense Mutation (SNP) | VAF 22/158 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADGRD2 | c.2208G>T p.M736I | Missense Mutation (SNP) | VAF 76/326 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.187); called by muse, varscan2
- AGER | c.679C>G p.P227A | Missense Mutation (SNP) | VAF 40/143 reads (28%) | SIFT tolerated (0.44); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- AHSP | c.35C>T p.S12F | Missense Mutation (SNP) | VAF 212/441 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- AKAP6 | c.2630G>C p.R877P | Missense Mutation (SNP) | VAF 44/122 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ALDH1A2 | c.251C>A p.A84D | Missense Mutation (SNP) | VAF 123/451 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ALG1L2 | c.434A>T p.D145V | Missense Mutation (SNP) | VAF 128/352 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- ANKHD1 | c.2143-1G>C p.X715_splice | Splice Site (SNP) | VAF 29/53 reads (55%) | called by muse, mutect2, varscan2
- ANKRD13B | c.1792G>A p.A598T | Missense Mutation (SNP) | VAF 114/358 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.24); called by muse, mutect2, varscan2
- ANKRD36C | c.790A>G p.S264G | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- ANO5 | c.280G>T p.A94S | Missense Mutation (SNP) | VAF 39/177 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- AP5Z1 | c.391G>T p.A131S | Missense Mutation (SNP) | VAF 64/176 reads (36%) | SIFT tolerated (0.97); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- APBB1IP | c.1874A>G p.K625R | Missense Mutation (SNP) | VAF 91/203 reads (45%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ARAP1 | c.719G>C p.G240A | Missense Mutation (SNP) | VAF 53/121 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- ARHGAP33 | c.1793G>T p.G598V | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ARID2 | c.3854A>G p.E1285G | Missense Mutation (SNP) | VAF 32/162 reads (20%) | SIFT tolerated, low confidence (0.29); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ASPM | c.9976G>C p.V3326L | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.048); called by muse, mutect2
- ATP2B3 | c.2743G>T p.G915C | Missense Mutation (SNP) | VAF 15/328 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- AVIL | c.1459G>A p.A487T | Missense Mutation (SNP) | VAF 168/581 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.802); called by muse, mutect2, varscan2
- BAHCC1 | c.3355A>T p.T1119S | Missense Mutation (SNP) | VAF 82/249 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.287); called by muse, mutect2, varscan2
- BARHL1 | c.103C>G p.P35A | Missense Mutation (SNP) | VAF 31/309 reads (10%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.426); called by muse, mutect2
- BRD2 | c.1867G>A p.A623T | Missense Mutation (SNP) | VAF 50/174 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0.01); called by mutect2, varscan2
- BRD8 | c.3420C>G p.Y1140* | Nonsense Mutation (SNP) | VAF 91/214 reads (43%) | called by muse, mutect2, varscan2
- C19orf73 | c.173G>A p.R58Q | Missense Mutation (SNP) | VAF 50/154 reads (32%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- CACNA2D1 | c.107G>T p.W36L | Missense Mutation (SNP) | VAF 46/211 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- CARD11 | c.2576A>G p.D859G | Missense Mutation (SNP) | VAF 32/310 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.063); called by muse, mutect2
- CASP8AP2 | c.1295G>A p.R432K | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CCDC138 | c.1772A>T p.K591M | Missense Mutation (SNP) | VAF 43/178 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); called by muse, mutect2, varscan2
- CCDC50 | c.761G>T p.W254L | Missense Mutation (SNP) | VAF 50/129 reads (39%) | SIFT tolerated (0.21); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- CCDC60 | c.1209C>G p.D403E | Missense Mutation (SNP) | VAF 45/252 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.352); called by muse, mutect2, varscan2
- CCNF | c.1283A>G p.Q428R | Missense Mutation (SNP) | VAF 160/338 reads (47%) | SIFT tolerated (0.53); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- CFAP300 | c.111-4C>G | Splice Region (SNP) | VAF 21/144 reads (15%) | called by muse, mutect2, varscan2
- CHCHD6 | c.257del p.G86Vfs*63 | Frame Shift Del (DEL) | VAF 60/215 reads (28%) | called by mutect2, pindel, varscan2
- CLASRP | c.1271G>A p.R424H | Missense Mutation (SNP) | VAF 156/543 reads (29%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.706); called by muse, mutect2, varscan2
- CLCF1 | c.477_479dup p.P159_Q160insH | In Frame Ins (INS) | VAF 39/169 reads (23%) | called by mutect2, pindel, varscan2
- CLEC2A | c.109A>G p.I37V | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated (0.93); PolyPhen benign (0); called by muse, mutect2, varscan2
- CLIC1 | c.176G>C p.C59S | Missense Mutation (SNP) | VAF 34/154 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- COL19A1 | c.1265C>A p.P422H | Missense Mutation (SNP) | VAF 48/216 reads (22%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL4A4 | c.2671G>T p.G891C | Missense Mutation (SNP) | VAF 76/188 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL6A6 | c.1100T>G p.I367R | Missense Mutation (SNP) | VAF 71/299 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- COPS3 | c.866A>C p.D289A | Missense Mutation (SNP) | VAF 62/207 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CORIN | c.2142_2143del p.A715Rfs*52 | Frame Shift Del (DEL) | VAF 41/171 reads (24%) | called by pindel, varscan2
- CRYBG3 | c.1882G>C p.E628Q | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.31); called by muse, mutect2, varscan2
- CUL7 | c.4085C>T p.A1362V | Missense Mutation (SNP) | VAF 145/417 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CUX1 | c.1139C>T p.P380L (on ENST00000292535 / NM_181552.4; = p.P391L on NM_001913.5) | Missense Mutation (SNP) | VAF 104/270 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- CYLC1 | c.1831G>T p.A611S | Missense Mutation (SNP) | VAF 46/79 reads (58%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.542); called by muse, mutect2, varscan2
- CYP2D7 | c.94C>A p.R32S | Missense Mutation (SNP) | VAF 190/688 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.176); called by muse, mutect2, varscan2
- DCHS1 | c.2311G>T p.E771* | Nonsense Mutation (SNP) | VAF 82/397 reads (21%) | called by muse, mutect2, varscan2
- DEPDC5 | c.3683G>T p.S1228I (on ENST00000400246; = p.S1297I on NM_014662.5) | Missense Mutation (SNP) | VAF 126/408 reads (31%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.959); called by mutect2, varscan2
- DNAAF4 | c.324A>T p.Q108H | Missense Mutation (SNP) | VAF 60/223 reads (27%) | SIFT tolerated (0.36); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- DNAH5 | c.8680C>A p.P2894T | Missense Mutation (SNP) | VAF 67/338 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DNAH9 | c.1583C>T p.T528I | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); called by muse, mutect2, varscan2
- DPP10 | c.815C>G p.A272G | Missense Mutation (SNP) | VAF 34/129 reads (26%) | SIFT tolerated (0.33); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DPP6 | c.2330C>G p.S777C (on ENST00000377770 / NM_001364500.2; = p.S715C on NM_001936.5) | Missense Mutation (SNP) | VAF 58/167 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.853); called by muse, mutect2, varscan2
- DPY19L4 | c.698C>T p.T233I | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DSTYK | c.932G>A p.G311D | Missense Mutation (SNP) | VAF 38/132 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.093); called by mutect2, varscan2
- DYNC2H1 | c.9289A>T p.I3097F | Missense Mutation (SNP) | VAF 95/311 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- EFNB3 | c.763dup p.R255Pfs*35 | Frame Shift Ins (INS) | VAF 10/54 reads (19%) | called by mutect2, pindel, varscan2
- ELMO1 | c.1847T>C p.V616A | Missense Mutation (SNP) | VAF 56/215 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- EP400 | c.4588G>A p.G1530S | Missense Mutation (SNP) | VAF 116/437 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EPHA2 | c.1609G>A p.V537M | Missense Mutation (SNP) | VAF 221/476 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- EPHA6 | c.1417T>A p.C473S | Missense Mutation (SNP) | VAF 90/237 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ERV3-1 | c.7G>T p.G3C | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated, low confidence (0.13); called by muse, mutect2, varscan2
- EYA4 | c.1016_1017insA p.T340Hfs*7 (on ENST00000531901 / NM_001301013.1; = p.T334Hfs*7 on NM_004100.5) | Frame Shift Ins (INS) | VAF 121/453 reads (27%) | called by mutect2, pindel, varscan2
- FAM71B | c.304T>A p.W102R | Missense Mutation (SNP) | VAF 113/259 reads (44%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM90A1 | c.512C>T p.T171I | Missense Mutation (SNP) | VAF 272/891 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- FBN2 | c.4107T>A p.D1369E | Missense Mutation (SNP) | VAF 105/271 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.301); called by muse, mutect2, varscan2
- FBN2 | c.2906G>A p.G969E | Missense Mutation (SNP) | VAF 153/339 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- FER1L6 | c.2970C>A p.S990R | Missense Mutation (SNP) | VAF 94/307 reads (31%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- FIGNL2 | c.1561G>A p.G521S | Missense Mutation (SNP) | VAF 206/491 reads (42%) | SIFT tolerated (0.61); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FSIP2 | c.5065G>A p.A1689T | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- GAA | c.2190G>A p.E730= | Splice Region (SNP) | VAF 39/354 reads (11%) | called by muse, mutect2, varscan2
- GABRA1 | c.1176T>A p.S392R | Missense Mutation (SNP) | VAF 79/194 reads (41%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- GMPPB | c.782G>T p.R261L | Missense Mutation (SNP) | VAF 41/78 reads (53%) | SIFT tolerated (0.08); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- GNG11 | c.120A>G p.I40M | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0.338); called by muse, mutect2, varscan2
- GNL3L | c.221C>G p.A74G | Missense Mutation (SNP) | VAF 69/115 reads (60%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.696); called by muse, mutect2, varscan2
- GPATCH8 | c.1084G>T p.E362* | Nonsense Mutation (SNP) | VAF 25/280 reads (9%) | called by muse, mutect2
- GPX5 | c.318G>C p.K106N | Missense Mutation (SNP) | VAF 119/381 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- GREB1L | c.1508C>A p.S503* | Nonsense Mutation (SNP) | VAF 77/285 reads (27%) | called by muse, mutect2, varscan2
- GREM1 | c.366C>A p.C122* | Nonsense Mutation (SNP) | VAF 162/481 reads (34%) | called by muse, mutect2, varscan2
- HCN1 | c.937G>T p.G313C | Missense Mutation (SNP) | VAF 53/282 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- HCN1 | c.125C>A p.P42Q | Missense Mutation (SNP) | VAF 55/221 reads (25%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- HDAC4 | c.1135C>G p.P379A | Missense Mutation (SNP) | VAF 51/492 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- HDGFL1 | c.50C>A p.A17D | Missense Mutation (SNP) | VAF 48/246 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGF2R | c.4173G>T p.W1391C | Missense Mutation (SNP) | VAF 89/346 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGKV1D-33 | c.107C>T p.S36F | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); called by mutect2, varscan2
- IGKV1D-39 | c.4G>T p.D2Y | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.949); called by mutect2, varscan2
- IGKV1D-42 | c.125G>T p.S42I | Missense Mutation (SNP) | VAF 58/202 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- IGKV6D-41 | c.34C>A p.L12I | Missense Mutation (SNP) | VAF 44/188 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.371); called by muse, mutect2, varscan2
- INSM2 | c.622G>T p.A208S | Missense Mutation (SNP) | VAF 55/126 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.033); called by mutect2, varscan2
- ITGAM | c.871T>C p.F291L | Missense Mutation (SNP) | VAF 52/104 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- KCNE5 | c.248G>T p.R83L | Missense Mutation (SNP) | VAF 183/293 reads (62%) | SIFT tolerated (0.07); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- KCNK13 | c.1105G>C p.E369Q | Missense Mutation (SNP) | VAF 68/156 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- KDM2B | c.1432G>T p.E478* | Nonsense Mutation (SNP) | VAF 92/371 reads (25%) | called by muse, mutect2, varscan2
- KHDRBS2 | c.697C>A p.L233I | Missense Mutation (SNP) | VAF 32/145 reads (22%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- KLHL29 | c.551G>T p.G184V | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- KLHL40 | c.149T>G p.V50G | Missense Mutation (SNP) | VAF 10/292 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2
- KRT7 | c.145G>A p.V49M | Missense Mutation (SNP) | VAF 130/381 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- LHFPL4 | c.50G>T p.R17L | Missense Mutation (SNP) | VAF 61/147 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LILRB1 | c.696G>T p.R232S (on ENST00000427581; = p.R196S on NM_006669.6) | Missense Mutation (SNP) | VAF 74/281 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- LLGL2 | c.556C>A p.R186S | Missense Mutation (SNP) | VAF 90/238 reads (38%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- LMTK3 | c.3215C>T p.P1072L | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- LRRC37A3 | c.4630G>T p.D1544Y | Missense Mutation (SNP) | VAF 48/554 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); called by muse, mutect2
- LRRC9 | c.48+2T>A p.X16_splice | Splice Site (SNP) | VAF 5/25 reads (20%) | called by muse, mutect2, varscan2
- MACF1 | c.11192C>T p.A3731V (on ENST00000372915; = p.A1664V on NM_012090.5) | Missense Mutation (SNP) | VAF 66/410 reads (16%) | called by muse, mutect2, varscan2
- MAGED2 | c.1351A>G p.T451A | Missense Mutation (SNP) | VAF 61/111 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); called by muse, mutect2, varscan2
- MARCO | c.610G>T p.A204S | Missense Mutation (SNP) | VAF 62/202 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.422); called by muse, mutect2, varscan2
- MMP17 | c.650_697del p.H217_F232del | In Frame Del (DEL) | VAF 19/180 reads (11%) | called by mutect2, pindel
- MMP20 | c.1204G>T p.E402* | Nonsense Mutation (SNP) | VAF 67/199 reads (34%) | called by muse, mutect2, varscan2
- MOV10 | c.132G>C p.K44N | Missense Mutation (SNP) | VAF 38/328 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- MPHOSPH10 | c.752G>T p.G251V | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- MPLKIP | c.288del p.S97Pfs*56 | Frame Shift Del (DEL) | VAF 103/380 reads (27%) | called by mutect2, pindel, varscan2
- MSLN | c.556G>C p.G186R | Missense Mutation (SNP) | VAF 69/176 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MUC5B | c.13007C>A p.T4336N | Missense Mutation (SNP) | VAF 136/476 reads (29%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MYH2 | c.5423A>T p.Q1808L | Missense Mutation (SNP) | VAF 172/573 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYH2 | c.2579A>T p.E860V | Missense Mutation (SNP) | VAF 106/367 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.367); called by muse, mutect2, varscan2
- MYH8 | c.2140A>T p.S714C | Missense Mutation (SNP) | VAF 50/253 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.351); called by muse, mutect2, varscan2
- MYO7A | c.6567G>C p.K2189N | Missense Mutation (SNP) | VAF 52/240 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NAV3 | c.6581del p.R2194Kfs*4 (on ENST00000397909 / NM_001024383.2; = p.R2172Kfs*4 on NM_014903.6) | Frame Shift Del (DEL) | VAF 26/125 reads (21%) | called by mutect2, pindel, varscan2
- NBEA | c.2611G>T p.D871Y | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- NCKAP1L | c.2527C>A p.L843I | Missense Mutation (SNP) | VAF 75/261 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.291); called by muse, mutect2, varscan2
- NEB | c.6247G>T p.D2083Y | Missense Mutation (SNP) | VAF 49/152 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NEO1 | c.4333A>G p.M1445V | Missense Mutation (SNP) | VAF 50/227 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NLRP13 | c.139G>A p.A47T | Missense Mutation (SNP) | VAF 67/256 reads (26%) | SIFT tolerated (0.48); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- NOTCH1 | c.2468-2A>T p.X823_splice | Splice Site (SNP) | VAF 41/171 reads (24%) | called by muse, mutect2, varscan2
- NRG3 | c.368dup p.A124Gfs*32 | Frame Shift Ins (INS) | VAF 115/275 reads (42%) | called by mutect2, pindel, varscan2
- NRG3 | c.1741A>T p.S581C (on ENST00000404547 / NM_001370084.1; = p.S557C on NM_001010848.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 93/218 reads (43%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- NTSR1 | c.92T>A p.L31Q | Missense Mutation (SNP) | VAF 189/553 reads (34%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- NUP107 | c.1637T>G p.L546R | Missense Mutation (SNP) | VAF 46/182 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- OR10J5 | c.733A>T p.T245S | Missense Mutation (SNP) | VAF 39/158 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- OR10Q1 | c.460G>T p.G154C | Missense Mutation (SNP) | VAF 97/326 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- OR14C36 | c.280G>C p.G94R | Missense Mutation (SNP) | VAF 72/301 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.323); called by muse, mutect2, varscan2
- OR1E1 | c.93C>G p.F31L | Missense Mutation (SNP) | VAF 42/205 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.242); called by muse, mutect2, varscan2
- OR4A15 | c.413T>A p.V138D | Missense Mutation (SNP) | VAF 74/249 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- OR4K13 | c.547C>T p.L183F | Missense Mutation (SNP) | VAF 86/177 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.334); called by muse, mutect2, varscan2
- OR4S1 | c.584T>C p.L195P | Missense Mutation (SNP) | VAF 58/224 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- OR52A1 | c.418C>A p.H140N | Missense Mutation (SNP) | VAF 45/117 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OR5A2 | c.731C>G p.S244C | Missense Mutation (SNP) | VAF 48/154 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR7C2 | c.461T>C p.M154T | Missense Mutation (SNP) | VAF 163/499 reads (33%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- OR8D2 | c.394T>C p.Y132H | Missense Mutation (SNP) | VAF 49/136 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PAK3 | c.1667A>G p.N556S (on ENST00000262836 / NM_001324328.2; = p.N541S on NM_002578.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 142/226 reads (63%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- PIEZO2 | c.5788A>G p.I1930V | Missense Mutation (SNP) | VAF 148/524 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- PKHD1 | c.3764C>T p.P1255L | Missense Mutation (SNP) | VAF 99/341 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- PLPPR3 | c.2089G>T p.E697* (on ENST00000520876 / NM_001270366.2; = p.E725* on NM_024888.2) | Nonsense Mutation (SNP) | VAF 51/148 reads (34%) | called by muse, mutect2, varscan2
- PLSCR5 | c.101G>T p.G34V | Missense Mutation (SNP) | VAF 106/289 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- POU3F2 | c.421C>G p.Q141E | Missense Mutation (SNP) | VAF 120/450 reads (27%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.033); called by mutect2, varscan2
- PPARD | c.508C>G p.P170A | Missense Mutation (SNP) | VAF 125/478 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- PPP1R14C | c.58C>G p.R20G | Missense Mutation (SNP) | VAF 31/108 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.585); called by muse, mutect2, varscan2
- PPP1R26 | c.1150G>A p.A384T | Missense Mutation (SNP) | VAF 76/243 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PPP1R3B | c.187G>T p.V63L | Missense Mutation (SNP) | VAF 86/215 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PRAG1 | c.99C>A p.C33* | Nonsense Mutation (SNP) | VAF 16/162 reads (10%) | called by muse, mutect2
- PSTPIP1 | c.700C>T p.H234Y | Missense Mutation (SNP) | VAF 94/346 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.591); called by muse, mutect2, varscan2
- PTGS1 | c.664G>T p.A222S | Missense Mutation (SNP) | VAF 49/166 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.35); called by muse, mutect2, varscan2
- PTPRM | c.1153A>G p.K385E | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.011); called by mutect2, varscan2
- R3HDM1 | c.2860G>T p.G954C | Missense Mutation (SNP) | VAF 59/171 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RAB8B | c.191C>A p.T64K | Missense Mutation (SNP) | VAF 50/188 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- RAB8B | c.193G>A p.A65T | Missense Mutation (SNP) | VAF 54/196 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, varscan2
- RBP3 | c.841C>A p.P281T | Missense Mutation (SNP) | VAF 88/224 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- REG3G | c.152G>T p.C51F | Missense Mutation (SNP) | VAF 44/176 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- RFPL4A | c.49G>T p.D17Y | Missense Mutation (SNP) | VAF 66/539 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, varscan2
- RGS12 | c.2956G>A p.D986N | Missense Mutation (SNP) | VAF 29/201 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.477); called by muse, mutect2, varscan2
- RGS12 | c.2957A>T p.D986V | Missense Mutation (SNP) | VAF 29/202 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); called by muse, mutect2, varscan2
- RIN2 | c.2361G>T p.L787F (on ENST00000255006 / NM_001242581.1; = p.L738F on NM_018993.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/117 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SATB2 | c.1741G>T p.V581L | Missense Mutation (SNP) | VAF 36/258 reads (14%) | SIFT tolerated (0.71); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- SCRN2 | c.1178C>T p.A393V | Missense Mutation (SNP) | VAF 153/416 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SCTR | c.539A>T p.H180L | Missense Mutation (SNP) | VAF 72/300 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- SDHAP3 | n.82G>T | Splice Region (SNP) | VAF 115/527 reads (22%) | called by muse, mutect2, varscan2
- SELP | c.907G>A p.V303M | Missense Mutation (SNP) | VAF 65/205 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- SEPTIN4 | c.1417C>A p.L473M | Missense Mutation (SNP) | VAF 67/274 reads (24%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- SERPINI1 | c.34C>A p.L12M | Missense Mutation (SNP) | VAF 16/320 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.054); called by muse, mutect2
- SFI1 | c.1460C>T p.P487L (on ENST00000400288 / NM_001007467.3; = p.P456L on NM_014775.4) | Missense Mutation (SNP) | VAF 65/233 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SGO2 | c.1387C>A p.Q463K | Missense Mutation (SNP) | VAF 20/220 reads (9%) | SIFT tolerated (0.31); PolyPhen benign (0.015); called by muse, mutect2
- SIM2 | c.107A>G p.Q36R | Missense Mutation (SNP) | VAF 97/545 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLC16A2 | c.1208T>C p.M403T | Missense Mutation (SNP) | VAF 76/121 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- SLC1A6 | c.79C>A p.Q27K | Missense Mutation (SNP) | VAF 150/497 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- SLC22A15 | c.544G>T p.V182L | Missense Mutation (SNP) | VAF 38/160 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- SLC24A5 | c.164C>A p.P55H | Missense Mutation (SNP) | VAF 89/267 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLC26A7 | c.1957C>A p.H653N | Missense Mutation (SNP) | VAF 29/151 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.321); called by muse, mutect2, varscan2
- SLC5A3 | c.463G>A p.G155S | Missense Mutation (SNP) | VAF 57/324 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC9A3 | c.1504dup p.Y502Lfs*48 | Frame Shift Ins (INS) | VAF 175/500 reads (35%) | called by mutect2, pindel, varscan2
- SMG1 | c.1238G>T p.G413V | Missense Mutation (SNP) | VAF 54/118 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SPOCK2 | c.1220C>G p.A407G | Missense Mutation (SNP) | VAF 92/177 reads (52%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- SPR | c.281G>C p.R94P | Missense Mutation (SNP) | VAF 70/249 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SPSB4 | c.139G>T p.G47W | Missense Mutation (SNP) | VAF 42/286 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.686); called by muse, mutect2, varscan2
- SREBF2 | c.1454G>T p.C485F | Missense Mutation (SNP) | VAF 120/479 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by mutect2, varscan2
- STARD3NL | c.538G>T p.A180S | Missense Mutation (SNP) | VAF 44/148 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.377); called by muse, mutect2, varscan2
- STARD9 | c.7713G>T p.R2571S | Missense Mutation (SNP) | VAF 87/257 reads (34%) | SIFT tolerated (0.39); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- STAT5B | c.1453G>C p.D485H | Missense Mutation (SNP) | VAF 161/594 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- STX6 | c.187G>A p.D63N | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SV2A | c.343G>A p.D115N | Missense Mutation (SNP) | VAF 36/162 reads (22%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- TAAR9 | c.707G>T p.S236I | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.056); called by muse, varscan2
- TARS2 | c.1249G>T p.A417S | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- TDRD15 | c.245T>A p.M82K | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- TDRD6 | c.4921A>G p.I1641V | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TEX13C | c.746C>A p.P249Q | Missense Mutation (SNP) | VAF 132/222 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TLR7 | c.641A>G p.N214S | Missense Mutation (SNP) | VAF 61/108 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- TMEM104 | c.898A>G p.K300E | Missense Mutation (SNP) | VAF 94/368 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMEM132D | c.2665C>A p.P889T | Missense Mutation (SNP) | VAF 85/278 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TMEM144 | c.625T>G p.Y209D | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- TNFSF12-TNFSF13 | c.244G>C p.A82P | Missense Mutation (SNP) | VAF 51/339 reads (15%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- TNRC18 | c.679G>A p.A227T | Missense Mutation (SNP) | VAF 18/219 reads (8%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.467); called by muse, mutect2
- TNXB | c.9641C>G p.S3214W (on ENST00000647633; = p.S2967W on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 131/476 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRGJP1 | c.5C>A p.T2N | Missense Mutation (SNP) | VAF 26/130 reads (20%) | called by muse, mutect2, varscan2
- TRIM77 | c.860T>A p.V287E | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.624); called by muse, mutect2, varscan2
- TRIP12 | c.3011G>T p.R1004L | Missense Mutation (SNP) | VAF 68/222 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- TRPC4 | c.1312G>T p.D438Y | Missense Mutation (SNP) | VAF 31/55 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TRPC5 | c.130G>A p.D44N | Missense Mutation (SNP) | VAF 84/153 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- TRPM7 | c.3116A>T p.H1039L | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- TTC21A | c.1734G>T p.K578N | Missense Mutation (SNP) | VAF 97/183 reads (53%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- TTN | c.38931G>C p.W12977C (on ENST00000591111; = p.W5553C on NM_003319.4) | Missense Mutation (SNP) | VAF 69/225 reads (31%) | PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TTN | c.13352G>T p.G4451V (on ENST00000591111; = p.G4405V on NM_003319.4) | Missense Mutation (SNP) | VAF 42/123 reads (34%) | PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- TTN | c.13351G>T p.G4451C (on ENST00000591111; = p.G4405C on NM_003319.4) | Missense Mutation (SNP) | VAF 44/133 reads (33%) | PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UBE2F | c.215-2A>G p.X72_splice | Splice Site (SNP) | VAF 14/105 reads (13%) | called by muse, mutect2, varscan2
- UBQLN4 | c.677A>G p.Q226R | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.641); called by muse, mutect2, varscan2
- USP13 | c.1378G>C p.E460Q | Missense Mutation (SNP) | VAF 45/190 reads (24%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- USP14 | c.196-1G>T p.X66_splice | Splice Site (SNP) | VAF 23/94 reads (24%) | called by muse, mutect2, varscan2
- USP14 | c.196G>T p.G66* | Nonsense Mutation (SNP) | VAF 23/95 reads (24%) | called by muse, mutect2, varscan2
- USP20 | c.2251G>T p.D751Y | Missense Mutation (SNP) | VAF 44/201 reads (22%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- USP28 | c.2299A>G p.S767G | Missense Mutation (SNP) | VAF 37/131 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- VCAN | c.188G>T p.R63L | Missense Mutation (SNP) | VAF 93/244 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- VPS13B | c.1108G>T p.D370Y | Missense Mutation (SNP) | VAF 58/269 reads (22%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- VPS13C | c.3362G>C p.R1121T (on ENST00000644861 / NM_020821.3; = p.R1078T on NM_017684.5) | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.34); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- VRK3 | c.20A>T p.D7V | Missense Mutation (SNP) | VAF 50/187 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- WDR64 | c.1544T>C p.F515S | Missense Mutation (SNP) | VAF 49/177 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- WNT9A | c.827G>T p.G276V | Missense Mutation (SNP) | VAF 71/319 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- YOD1 | c.926A>T p.Q309L | Missense Mutation (SNP) | VAF 62/254 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- Z83844.2 | c.796G>A p.D266N | Missense Mutation (SNP) | VAF 64/202 reads (32%) | SIFT tolerated (0.28); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ZNF208 | c.3523_3524insT p.G1175Vfs*14 | Frame Shift Ins (INS) | VAF 34/163 reads (21%) | called by mutect2, pindel, varscan2
- ZNF451 | c.1318G>T p.E440* | Nonsense Mutation (SNP) | VAF 41/135 reads (30%) | called by muse, mutect2, varscan2
- ZNF738 | c.97-1G>T p.X33_splice | Splice Site (SNP) | VAF 24/95 reads (25%) | called by muse, varscan2
- ZNF835 | c.886C>A p.H296N | Missense Mutation (SNP) | VAF 133/485 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF837 | c.1196C>T p.A399V | Missense Mutation (SNP) | VAF 90/354 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); called by muse, mutect2, varscan2
- AASDH | c.1815A>G p.T605= | Silent (SNP) | VAF 202/371 reads (54%) | called by muse, mutect2, varscan2
- ABCG4 | c.1848C>A p.L616= | Silent (SNP) | VAF 93/321 reads (29%) | called by muse, mutect2, varscan2
- ADSS2 | c.93G>T p.T31= | Silent (SNP) | VAF 177/409 reads (43%) | called by muse, mutect2, varscan2
- AKAP6 | c.2631G>T p.R877= | Silent (SNP) | VAF 46/123 reads (37%) | catalogued as rs753018110, COSV55236110; called by muse, mutect2, varscan2
- ALDH1A2 | c.252C>G p.A84= | Silent (SNP) | VAF 126/458 reads (28%) | called by muse, mutect2, varscan2
- ANGPT4 | c.648C>A p.I216= | Silent (SNP) | VAF 98/324 reads (30%) | called by muse, varscan2
- ANKRD18A | c.114C>A p.I38= | Silent (SNP) | VAF 239/614 reads (39%) | called by muse, mutect2, varscan2
- ANKRD35 | c.2529G>A p.V843= | Silent (SNP) | VAF 62/157 reads (39%) | called by muse, mutect2, varscan2
- ANKS6 | c.1305C>T p.P435= | Silent (SNP) | VAF 117/345 reads (34%) | catalogued as COSV100782372; called by muse, mutect2, varscan2
- AOAH | c.1575C>A p.P525= | Silent (SNP) | VAF 55/200 reads (28%) | catalogued as COSV51741626, COSV51751897; called by muse, mutect2, varscan2
- ARHGEF2 | c.390C>T p.L130= | Silent (SNP) | VAF 52/239 reads (22%) | called by muse, mutect2, varscan2
- ATP9B | c.609G>A p.R203= | Silent (SNP) | VAF 22/109 reads (20%) | called by muse, mutect2, varscan2
- BAAT | c.1236A>T p.P412= | Silent (SNP) | VAF 55/250 reads (22%) | called by muse, mutect2, varscan2
- C6 | c.2424C>T p.N808= | Silent (SNP) | VAF 71/312 reads (23%) | catalogued as rs778212785, COSV54718625; called by muse, mutect2, varscan2
- CACNA2D1 | c.558A>T p.T186= | Silent (SNP) | VAF 69/281 reads (25%) | called by muse, mutect2, varscan2
- CACNG3 | c.936C>A p.T312= | Silent (SNP) | VAF 45/78 reads (58%) | catalogued as COSV50066537; called by muse, mutect2, varscan2
- CACNG7 | c.267C>T p.N89= | Silent (SNP) | VAF 41/189 reads (22%) | called by muse, mutect2, varscan2
- CDH12 | c.300C>A p.T100= | Silent (SNP) | VAF 58/234 reads (25%) | catalogued as COSV66424241; called by muse, mutect2, varscan2
- CDH4 | c.522G>A p.P174= | Silent (SNP) | VAF 52/330 reads (16%) | catalogued as rs763267948, COSV100848764; called by muse, mutect2, varscan2
- CEP170 | c.4065T>C p.V1355= | Silent (SNP) | VAF 30/100 reads (30%) | catalogued as rs1354329827; called by muse, mutect2, varscan2
- CFHR4 | c.618T>C p.S206= (on ENST00000367416 / NM_001201551.2; = p.S207= on NM_001201550.3) | Silent (SNP) | VAF 39/168 reads (23%) | catalogued as rs1553303291; called by muse, mutect2, varscan2
- CHRM5 | c.1539A>C p.R513= | Silent (SNP) | VAF 55/196 reads (28%) | called by muse, mutect2, varscan2
- CNR1 | c.762C>A p.G254= | Silent (SNP) | VAF 96/296 reads (32%) | catalogued as COSV62986715; called by muse, mutect2, varscan2
- COL11A1 | c.1119G>A p.L373= | Silent (SNP) | VAF 21/148 reads (14%) | catalogued as rs1434720892; called by muse, mutect2, varscan2
- COL6A1 | c.93C>T p.F31= | Silent (SNP) | VAF 149/499 reads (30%) | catalogued as rs753371577; called by muse, mutect2, varscan2
- DCAF12L2 | c.39G>T p.A13= | Silent (SNP) | VAF 139/265 reads (52%) | catalogued as rs745912706, COSV100758604, COSV63581893; called by muse, mutect2, varscan2
- DCC | c.1653T>G p.P551= | Silent (SNP) | VAF 103/497 reads (21%) | called by muse, mutect2, varscan2
- DLG4 | c.1155G>T p.T385= (on ENST00000399506 / NM_001321075.3; = p.T428= on NM_001365.4) | Silent (SNP) | VAF 125/430 reads (29%) | called by muse, mutect2
- DOCK7 | c.870C>G p.V290= | Silent (SNP) | VAF 7/47 reads (15%) | catalogued as COSV99223272; called by muse, mutect2, varscan2
- DPP10 | c.816G>T p.A272= | Silent (SNP) | VAF 32/128 reads (25%) | catalogued as COSV59691032; called by muse, mutect2, varscan2
- ESYT2 | c.2346G>T p.L782= (on ENST00000613624; = p.L706= on NM_020728.3) | Silent (SNP) | VAF 56/225 reads (25%) | called by muse, mutect2, varscan2
- FAM135B | c.213C>A p.V71= | Silent (SNP) | VAF 34/170 reads (20%) | catalogued as COSV50536631; called by muse, mutect2, varscan2
- FCGBP | c.45C>A p.T15= | Silent (SNP) | VAF 83/304 reads (27%) | catalogued as rs766654157; called by muse, mutect2, varscan2
- FCN2 | c.585G>A p.L195= | Silent (SNP) | VAF 68/304 reads (22%) | called by muse, mutect2, varscan2
- FEZF1 | c.567T>A p.P189= | Silent (SNP) | VAF 90/269 reads (33%) | called by muse, mutect2, varscan2
- FYN | c.162C>T p.H54= | Silent (SNP) | VAF 34/406 reads (8%) | catalogued as rs149406200; called by muse, mutect2
- GABRB2 | c.1467G>C p.R489= (on ENST00000274547; = p.R451= on NM_000813.3) | Silent (SNP) | VAF 79/188 reads (42%) | called by muse, mutect2, varscan2
- GLI4 | c.408C>T p.C136= | Silent (SNP) | VAF 96/306 reads (31%) | called by muse, mutect2, varscan2
- GLP2R | c.1467G>A p.K489= | Silent (SNP) | VAF 97/417 reads (23%) | called by muse, mutect2, varscan2
- GRID1 | c.1506C>T p.N502= | Silent (SNP) | VAF 73/162 reads (45%) | catalogued as rs201170791; called by muse, mutect2, varscan2
- H2BC10 | c.195C>A p.S65= | Silent (SNP) | VAF 96/359 reads (27%) | called by muse, mutect2, varscan2
- HEATR5B | c.5175G>T p.R1725= | Silent (SNP) | VAF 136/466 reads (29%) | called by muse, mutect2, varscan2
- HNF1A | c.741C>T p.S247= | Silent (SNP) | VAF 185/595 reads (31%) | called by muse, mutect2, varscan2
- HPCAL4 | c.153C>G p.L51= | Silent (SNP) | VAF 42/263 reads (16%) | called by muse, mutect2, varscan2
- HS3ST6 | c.342C>G p.P114= | Silent (SNP) | VAF 8/160 reads (5%) | called by muse, mutect2
- HUWE1 | c.5109G>T p.T1703= | Silent (SNP) | VAF 60/99 reads (61%) | called by muse, mutect2, varscan2
- KCNA1 | c.177C>A p.P59= | Silent (SNP) | VAF 163/581 reads (28%) | called by muse, mutect2, varscan2
- KCNG3 | c.306C>T p.G102= | Silent (SNP) | VAF 183/638 reads (29%) | catalogued as rs769354044; called by muse, mutect2, varscan2
- KCNJ12 | c.1104G>T p.L368= | Silent (SNP) | VAF 70/350 reads (20%) | called by muse, mutect2, varscan2
- KDM4B | c.1149G>A p.P383= | Silent (SNP) | VAF 112/325 reads (34%) | catalogued as rs552655191, COSV50274010; called by muse, mutect2, varscan2
- KIR3DL1 | c.1050C>A p.I350= | Silent (SNP) | VAF 91/340 reads (27%) | catalogued as rs374398136; called by muse, mutect2, varscan2
- KLHL6 | c.1836C>T p.R612= | Silent (SNP) | VAF 30/100 reads (30%) | catalogued as rs776676559; called by muse, mutect2
- LAMA5 | c.10665C>A p.T3555= | Silent (SNP) | VAF 78/245 reads (32%) | called by muse, mutect2, varscan2
- LDLRAD4 | c.604C>A p.R202= | Silent (SNP) | VAF 121/366 reads (33%) | called by muse, mutect2, varscan2
- LMOD2 | c.987G>T p.L329= | Silent (SNP) | VAF 50/192 reads (26%) | catalogued as rs1562951532; called by muse, mutect2, varscan2
- LRPAP1 | c.789G>T p.L263= | Silent (SNP) | VAF 103/288 reads (36%) | called by muse, mutect2, varscan2
- MAP6 | c.6G>A p.A2= | Silent (SNP) | VAF 82/265 reads (31%) | catalogued as rs1371726653; called by muse, mutect2, varscan2
- MAPKBP1 | c.588C>T p.G196= | Silent (SNP) | VAF 6/147 reads (4%) | called by muse, mutect2
- MED12L | c.5217C>T p.P1739= | Silent (SNP) | VAF 143/366 reads (39%) | catalogued as rs1317006783, COSV56391131; called by muse, mutect2, varscan2
- MUC17 | c.9492T>C p.T3164= | Silent (SNP) | VAF 58/228 reads (25%) | catalogued as rs1451527426, COSV60287676; called by muse, mutect2, varscan2
- MUC5B | c.5721C>T p.L1907= | Silent (SNP) | VAF 162/577 reads (28%) | catalogued as rs755948967; called by muse, mutect2, varscan2
- MYO5B | c.2403C>T p.H801= | Silent (SNP) | VAF 131/391 reads (34%) | catalogued as rs200132129; called by muse, mutect2, varscan2
- NEO1 | c.4332G>A p.E1444= | Silent (SNP) | VAF 49/223 reads (22%) | called by muse, mutect2, varscan2
- NLRC5 | c.2472A>G p.L824= | Silent (SNP) | VAF 89/214 reads (42%) | catalogued as rs1265381969; called by muse, mutect2, varscan2
- NUP205 | c.4251G>A p.V1417= | Silent (SNP) | VAF 42/152 reads (28%) | called by muse, mutect2, varscan2
- OR10A6 | c.750A>G p.L250= | Silent (SNP) | VAF 47/146 reads (32%) | catalogued as rs756450019; called by muse, mutect2, varscan2
- OR2T3 | c.744C>A p.S248= | Silent (SNP) | VAF 58/229 reads (25%) | catalogued as COSV62082857; called by muse, mutect2, varscan2
- OR4C12 | c.21G>T p.V7= | Silent (SNP) | VAF 20/75 reads (27%) | called by mutect2, varscan2
- OR4S1 | c.585C>T p.L195= | Silent (SNP) | VAF 58/229 reads (25%) | called by muse, mutect2, varscan2
- OR51C1P | c.201C>T p.S67= | Silent (SNP) | VAF 28/69 reads (41%) | catalogued as rs1167963481, COSV63326959; called by muse, mutect2, varscan2
- PAPPA2 | c.1611C>G p.G537= | Silent (SNP) | VAF 62/219 reads (28%) | called by muse, mutect2, varscan2
- PAPPA2 | c.2646C>T p.G882= | Silent (SNP) | VAF 51/198 reads (26%) | catalogued as rs201893312, COSV62777230; called by muse, mutect2, varscan2
- PCDH11X | c.3210G>C p.L1070= | Silent (SNP) | VAF 179/306 reads (58%) | called by muse, mutect2, varscan2
- PCM1 | c.2928C>T p.I976= | Silent (SNP) | VAF 38/105 reads (36%) | called by muse, mutect2, varscan2
- PCNX2 | c.4704C>T p.Y1568= | Silent (SNP) | VAF 52/167 reads (31%) | called by muse, mutect2, varscan2
- PLEKHA6 | c.2628G>C p.L876= | Silent (SNP) | VAF 95/284 reads (33%) | called by muse, mutect2, varscan2
- PLEKHG4B | c.1203G>T p.L401= (on ENST00000283426; = p.L757= on NM_052909.5) | Silent (SNP) | VAF 44/112 reads (39%) | called by muse, mutect2, varscan2
- PODN | c.1617C>A p.A539= (on ENST00000395871; = p.A491= on NM_153703.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as COSV57013560; called by muse, mutect2, varscan2
- PTPRS | c.1473G>T p.L491= | Silent (SNP) | VAF 80/285 reads (28%) | called by muse, varscan2
- RAB8B | c.192A>G p.T64= | Silent (SNP) | VAF 50/190 reads (26%) | called by muse, varscan2
- RASGRP3 | c.891C>T p.F297= | Silent (SNP) | VAF 73/343 reads (21%) | called by muse, mutect2, varscan2
- RELN | c.1056T>C p.N352= | Silent (SNP) | VAF 131/551 reads (24%) | called by muse, mutect2, varscan2
- RETSAT | c.153G>A p.R51= | Silent (SNP) | VAF 121/398 reads (30%) | called by muse, mutect2, varscan2
- SCN1A | c.5031C>A p.L1677= (on ENST00000303395 / NM_001202435.3; = p.L1666= on NM_006920.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 66/223 reads (30%) | called by muse, mutect2, varscan2
- SETX | c.7959C>T p.T2653= | Silent (SNP) | VAF 67/260 reads (26%) | called by muse, mutect2, varscan2
- SHISA9 | c.54C>A p.A18= | Silent (SNP) | VAF 17/375 reads (5%) | called by muse, mutect2
- SHROOM2 | c.1155G>T p.P385= | Silent (SNP) | VAF 91/137 reads (66%) | called by muse, mutect2, varscan2
- SLAMF1 | c.465C>T p.N155= | Silent (SNP) | VAF 69/198 reads (35%) | catalogued as rs773729465, COSV52498867; called by muse, mutect2, varscan2
- SLC6A4 | c.1680G>T p.P560= | Silent (SNP) | VAF 20/100 reads (20%) | catalogued as COSV55566701; called by muse, mutect2
- SLC8A1 | c.744C>T p.F248= | Silent (SNP) | VAF 37/250 reads (15%) | catalogued as rs750644440, COSV60470589; called by muse, mutect2, varscan2
- SPHKAP | c.1324C>A p.R442= | Silent (SNP) | VAF 47/171 reads (27%) | catalogued as COSV60885166; called by muse, mutect2, varscan2
- SPRED1 | c.930A>G p.V310= | Silent (SNP) | VAF 59/436 reads (14%) | catalogued as rs1164761920; called by muse, mutect2, varscan2
- SSC5D | c.3723C>G p.P1241= | Silent (SNP) | VAF 28/94 reads (30%) | called by muse, varscan2
- ST6GAL2 | c.819G>A p.A273= | Silent (SNP) | VAF 41/146 reads (28%) | catalogued as rs1437979462, COSV64527305; called by muse, mutect2, varscan2
- SVEP1 | c.1170C>A p.I390= | Silent (SNP) | VAF 39/123 reads (32%) | catalogued as COSV57027584; called by muse, mutect2, varscan2
- SYNE1 | c.24108G>A p.K8036= (on ENST00000367255 / NM_182961.4; = p.K7965= on NM_033071.3) | Silent (SNP) | VAF 50/168 reads (30%) | called by muse, mutect2, varscan2
- TBC1D9B | c.39G>T p.A13= | Silent (SNP) | VAF 113/259 reads (44%) | called by muse, mutect2, varscan2
- TCF4 | c.1374C>T p.G458= | Silent (SNP) | VAF 157/477 reads (33%) | called by muse, mutect2, varscan2
- TMPRSS15 | c.2589C>A p.V863= | Silent (SNP) | VAF 34/166 reads (20%) | called by muse, mutect2, varscan2
- TMPRSS15 | c.1500G>T p.G500= | Silent (SNP) | VAF 30/141 reads (21%) | catalogued as rs1235232852, COSV53034978, COSV53036761; called by muse, mutect2, varscan2
- TNIP3 | c.267G>C p.R89= | Silent (SNP) | VAF 130/353 reads (37%) | called by muse, mutect2, varscan2
- TRGV9 | c.291G>A p.T97= | Silent (SNP) | VAF 86/265 reads (32%) | catalogued as rs745480565; called by muse, mutect2, varscan2
- TTC25 | c.732G>T p.P244= | Silent (SNP) | VAF 189/547 reads (35%) | called by muse, mutect2, varscan2
- VPS18 | c.1938C>A p.I646= | Silent (SNP) | VAF 111/374 reads (30%) | called by muse, mutect2, varscan2
- VWA8 | c.5349G>A p.K1783= | Silent (SNP) | VAF 33/75 reads (44%) | called by muse, mutect2, varscan2
- XRN1 | c.4674G>C p.S1558= | Silent (SNP) | VAF 23/118 reads (19%) | catalogued as COSV53808773; called by muse, mutect2, varscan2
- ZNF202 | c.627C>T p.P209= | Silent (SNP) | VAF 76/281 reads (27%) | catalogued as rs755680190, COSV100278909; called by muse, mutect2, varscan2
- ZNF208 | c.1908C>A p.P636= | Silent (SNP) | VAF 30/301 reads (10%) | catalogued as rs1427668778, COSV101236986; called by muse, varscan2
- ZNF385A | c.843C>A p.S281= (on ENST00000338010 / NM_001130967.3; = p.S261= on NM_015481.3) | Silent (SNP) | VAF 100/302 reads (33%) | catalogued as rs1188714088, COSV61492960; called by muse, mutect2, varscan2
- ZNF497 | c.1188C>A p.R396= | Silent (SNP) | VAF 105/345 reads (30%) | catalogued as COSV54051192; called by muse, mutect2, varscan2
- ZNF544 | c.1443A>G p.T481= | Silent (SNP) | VAF 38/114 reads (33%) | called by muse, mutect2, varscan2
- ZNF671 | c.1482C>T p.L494= | Silent (SNP) | VAF 52/250 reads (21%) | catalogued as rs1276424035; called by muse, mutect2, varscan2
- AC058822.1 | c.1018-288041del | Intron (DEL) | VAF 101/239 reads (42%) | called by mutect2, pindel, varscan2
- ADAM12 | c.2113+840C>A | Intron (SNP) | VAF 113/252 reads (45%) | called by muse, mutect2, varscan2
- AGBL1 | c.*20G>A | 3'UTR (SNP) | VAF 31/126 reads (25%) | catalogued as COSV101480063; called by muse, mutect2, varscan2
- ANKH | c.96+16G>C | Intron (SNP) | VAF 66/337 reads (20%) | called by muse, mutect2, varscan2
- ANKRD26P1 | n.2060C>A | RNA (SNP) | VAF 8/28 reads (29%) | called by muse, mutect2, varscan2
- ASPH | c.323-11718A>C | Intron (SNP) | VAF 35/151 reads (23%) | called by muse, mutect2, varscan2
- ATL2 | c.119-15003G>T | Intron (SNP) | VAF 9/40 reads (23%) | catalogued as rs1346686516; called by muse, mutect2, varscan2
- BSCL2 | c.962-33G>T | Intron (SNP) | VAF 213/678 reads (31%) | called by mutect2, varscan2
- C6orf223 | n.363C>A | RNA (SNP) | VAF 46/158 reads (29%) | called by muse, mutect2, varscan2
- CHRDL2 | c.*9T>A | 3'UTR (SNP) | VAF 45/159 reads (28%) | called by muse, mutect2, varscan2
- CHRND | c.*459T>G | 3'UTR (SNP) | VAF 16/174 reads (9%) | called by muse, mutect2
- COL6A2 | c.2462-2492del | Intron (DEL) | VAF 19/80 reads (24%) | called by mutect2, pindel, varscan2
- CXADRP2 | n.126G>T | RNA (SNP) | VAF 22/110 reads (20%) | called by mutect2, varscan2
- DPP6 | c.*423G>T | 3'UTR (SNP) | VAF 85/293 reads (29%) | called by muse, mutect2, varscan2
- ERVV-1 | chr19:53009985 G>A | 5'Flank (SNP) | VAF 39/162 reads (24%) | called by muse, mutect2, varscan2
- ERVV-1 | chr19:53010742 T>A | 5'Flank (SNP) | VAF 6/24 reads (25%) | called by muse, mutect2, varscan2
- FAM167A | c.381+5919C>G | Intron (SNP) | VAF 46/146 reads (32%) | called by muse, mutect2, varscan2
- FGA | c.*14G>T | 3'UTR (SNP) | VAF 73/155 reads (47%) | called by muse, mutect2, varscan2
- FLRT2 | chr14:85528769 G>A | 5'Flank (SNP) | VAF 41/96 reads (43%) | called by muse, mutect2, varscan2
- FTH1 | chr11:61959834 T>C | 3'Flank (SNP) | VAF 49/201 reads (24%) | called by muse, mutect2, varscan2
- GVINP1 | n.6699A>G | RNA (SNP) | VAF 22/93 reads (24%) | called by muse, mutect2, varscan2
- HBA2 | c.300+40G>A | Intron (SNP) | VAF 217/608 reads (36%) | called by muse, mutect2, varscan2
- HERC2P3 | n.1584G>T | RNA (SNP) | VAF 133/466 reads (29%) | called by muse, mutect2, varscan2
- IGSF3 | c.1222+1402G>T | Intron (SNP) | VAF 61/182 reads (34%) | called by muse, mutect2, varscan2
- JPH3 | chr16:87701776 C>A | 3'Flank (SNP) | VAF 110/268 reads (41%) | called by muse, mutect2, varscan2
- KCNAB1 | c.275+22430G>A | Intron (SNP) | VAF 30/160 reads (19%) | called by muse, mutect2, varscan2
- KCNK16 | c.802+11C>A | Intron (SNP) | VAF 96/354 reads (27%) | catalogued as COSV64678724; called by muse, mutect2
- LINC01193 | n.792G>A | RNA (SNP) | VAF 71/581 reads (12%) | called by muse, mutect2, varscan2
- MLIP | c.612+12057A>T | Intron (SNP) | VAF 50/145 reads (34%) | called by muse, mutect2, varscan2
- MS4A6A | c.-228G>C | 5'UTR (SNP) | VAF 13/64 reads (20%) | called by muse, mutect2, varscan2
- PAXBP1 | c.1508-13T>C | Intron (SNP) | VAF 19/70 reads (27%) | called by muse, mutect2, varscan2
- PKLR | c.-39C>G | 5'UTR (SNP) | VAF 65/228 reads (29%) | called by muse, mutect2, varscan2
- PLEKHA5 | c.228-53587G>T | Intron (SNP) | VAF 6/29 reads (21%) | called by muse, mutect2, varscan2
- PLXNA4 | c.1371+4299A>T | Intron (SNP) | VAF 71/265 reads (27%) | catalogued as rs750094021; called by muse, mutect2, varscan2
- PNMA6A | chrX:153076187 A>G | 3'Flank (SNP) | VAF 6/12 reads (50%) | called by mutect2, varscan2
- POLE | c.6658-313A>G | Intron (SNP) | VAF 42/420 reads (10%) | called by muse, mutect2
- PPDPF | c.133+31G>T | Intron (SNP) | VAF 55/208 reads (26%) | catalogued as rs765311643; called by muse, mutect2, varscan2
- QSER1 | c.*30G>A | 3'UTR (SNP) | VAF 26/125 reads (21%) | called by muse, mutect2, varscan2
- RBM12B | c.-78+386G>T | Intron (SNP) | VAF 85/256 reads (33%) | catalogued as rs1394850840; called by muse, mutect2, varscan2
- SBDS | c.-45G>A | 5'UTR (SNP) | VAF 83/235 reads (35%) | called by muse, mutect2, varscan2
- SHOC2 | c.-235+17421C>T | Intron (SNP) | VAF 158/396 reads (40%) | called by muse, varscan2
- SHROOM3 | c.324-19C>G | Intron (SNP) | VAF 331/545 reads (61%) | called by muse, mutect2, varscan2
- SLC66A1L | n.443+6252C>A | Intron (SNP) | VAF 9/61 reads (15%) | called by muse, mutect2, varscan2
- SLC7A2 | c.-6G>A | 5'UTR (SNP) | VAF 32/66 reads (48%) | catalogued as rs367615909; called by muse, varscan2
- SYT14 | chr1:210163439 T>C | 3'Flank (SNP) | VAF 57/210 reads (27%) | called by muse, mutect2, varscan2
- TMEM135 | c.*2207del | 3'UTR (DEL) | VAF 14/57 reads (25%) | called by mutect2, pindel, varscan2
- TMEM182 | chr2:102758445 ins A | 5'Flank (INS) | VAF 13/49 reads (27%) | catalogued as rs756545733; called by mutect2, pindel, varscan2
- TMEM70 | c.-61C>T | 5'UTR (SNP) | VAF 106/319 reads (33%) | catalogued as rs750271273; called by muse, mutect2, varscan2
- TNFRSF25 | c.*244C>T | 3'UTR (SNP) | VAF 9/205 reads (4%) | called by muse, mutect2
- TRPM4 | c.3640+28C>T | Intron (SNP) | VAF 92/386 reads (24%) | called by muse, mutect2, varscan2
- TTN | c.34265-3033A>T | Intron (SNP) | VAF 65/271 reads (24%) | called by muse, mutect2, varscan2
- UQCRB | c.*805A>G | 3'UTR (SNP) | VAF 5/20 reads (25%) | catalogued as rs1333756837; called by muse, mutect2, varscan2
- USP14 | c.-4C>T | 5'UTR (SNP) | VAF 40/336 reads (12%) | catalogued as rs750981744; called by muse, mutect2, varscan2
- Unknown | chr2:111238176 C>T | IGR (SNP) | VAF 49/142 reads (35%) | called by muse, mutect2, varscan2
- VN1R10P | n.650A>T | RNA (SNP) | VAF 49/162 reads (30%) | called by muse, mutect2, varscan2
- VPS51 | c.2089-110C>T | Intron (SNP) | VAF 28/180 reads (16%) | called by muse, mutect2, varscan2
- XIST | n.7489C>A | RNA (SNP) | VAF 40/65 reads (62%) | called by muse, mutect2, varscan2
